Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q4-06A (Metastatic).

[page 1 of 2]
Melanoma NOS 8720/3
Sit.: lymph node, NOS C77.9
3/15/11 *lu*

(A) LEFT CALF, SKIN ELLIPSE:

NOTE: There is no malignant melanoma identified in these sections. Margins have been evaluated.

(B) LEFT SUPERFICIAL INGUINAL LYMPH NODE:

**METASTATIC MALIGNANT MELANOMA IN 1 OF 8 LYMPH NODES (1/6).
LARGEST METASTATIC FOCUS MEASURES 40.0 MM.
EXTRANODAL EXTENSION PRESENT.**

(C) RIGHT TOE PLANTAR, EXCISION:

Giant cell tumor of tendon sheath, biopsied.

(D) LEFT ILIAC AND OBTURATOR LYMPH NODES:

Six lymph nodes, negative for metastatic melanoma (0/6).

Entire report and diagnosis completed by \

	Yes	No
Criteria		
Met Malignancy History		

Date: 3/15/11

(A) WLE LEFT CALF - A skin ellipse (8.0 x 3.4 x 2.8 cm) with underlying subcutaneous tissue. On the epidermal surface is a 1.5 cm irregular scar, located at the central portion of the specimen. A short stitch designates superior; a long stitch designates posterior. The specimen is serially sectioned from anterior to posterior. No lesions are identified.

SECTION CODE: A1, anterior tip e face; A2, posterior tip en face; A3-A5, one slice divided in three cassettes (scar); A6-A11, one slice divided into six cassettes (scar). The scar is entirely submitted.

INK CODE: Blue - superior - deep; black - tip; blue - inferior -

(B) LEFT SUPERFICIAL INGUINAL LYMPH NODES - A unremarkable skin ellipse (14.0 x 1.5 x 0.3 cm and underlying soft tissue 30.0 x 9.0 x 4.0 cm). Both lymph nodes are dissected and range in size from 0.5 cm to 4.0 cm in diameter. The larger lymph node is grossly affected by metastatic disease.

SECTION CODE: B1, one lymph node bisected; B2, one lymph node bisected; B3, one lymph node trisected; B4-B5, multiple lymph nodes per cassette; B6, B7, larger lymph node (representative sections); B8, skin. Half portion of the larger lymph node is submitted for Tissue Bank.

(C) RIGHT TOE PLANTAR NEST - A 0.8 cm tan-firm and tan-brown firm lymph node. Submitted in toto in cassette C.

(D) LEFT ILIAC AND OBTURATOR LYMPH NODE - A 7.0 x 4.0 x 1.2 cm portion of fibroadipose tissue. Multiple lymph nodes are dissected and excised from 0.3 cm to 2.1 cm in diameter.

SECTION CODE: D1, one lymph node dissected; D2, one lymph node; D3, one lymph node; D4, one lymph node; D5, one lymph node; D6, one lymph node.

None given.

SNOMED CODES

[page 2 of 2]
Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 345a805b-253f-44c6-a119-19876a856148 (TCGA-D3-A1Q4.17F12722-DFAB-4D9B-8B1A-ECD55E4C70FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).